CGCI case BLGSP-71-21-00243 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d11efd71-b393-4ef9-be25-99005a68f93e

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 63.7 years (23,274 days); Year of diagnosis: 2016; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 729 days (2.0 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Neck; Sites of involvement: Neck / Tonsil.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Cervical, NOS; Tumor largest dimension diameter: 2.7 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 729 days (2.0 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day 0, day 664.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD10: Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD3: Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 458 [Blood test normal range upper: 210].

Other clinical attributes
- Day 0: Weight: 101.2 kg; Height: 181.6 cm; BMI: 30.7.

Biospecimens (3 samples)
- Sample BLGSP-71-21-00243-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Prospective.
- Sample BLGSP-71-21-00243-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-21-00243-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen; Days to sample procurement: 88 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Extranodal involvment other: Tonsil; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 458.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD3.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
